Somatic mutation profile of tumor specimen 0DKFA4 from CCDI case PBBYHF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infantile fibrosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 0.2 years (84 days).
Specimen 0DKFA4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7be67be8-9098-4b5d-b714-db6eec6159ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKF9Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7da1bca-f5cb-476e-acc5-7a8ab8fafd95

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY5 | c.2633C>T p.A878V | Missense Mutation (SNP) | VAF 148/625 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs982933713; called by muse, mutect2, varscan2
- TTC28 | c.4963G>A p.V1655M | Missense Mutation (SNP) | VAF 160/374 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs765658565; called by muse, mutect2, varscan2
